Somatic mutation profile of tumor specimen ER-B0CR-TTP1-A (aliquot ER-B0CR-TTP1-A-1-0-D-A668-34) from EXCEPTIONAL_RESPONDERS case ER-B0CR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.3 years (23,120 days).
Specimen ER-B0CR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48529f86-9216-4239-879b-1d9546b47749.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0CR-NT1-A (Solid Tissue Normal), aliquot ER-B0CR-NT1-A-1-0-D-A668-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cec507d-520a-41d9-b521-4d09b41cbbd6

The open-access MAF lists 92 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 22, Nonsense Mutation 6, Splice Site 3, Intron 1, Frame Shift Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4645C>T p.Q1549* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as rs863225357, COSV57334229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GREB1L | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as rs1555648043, COSV52566130; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPA1 | c.2873_2876del p.X958_splice (on ENST00000361510 / NM_130837.3; = p.X903_splice on NM_015560.3) | Splice Site (DEL) | VAF 5/51 reads (10%) | catalogued as rs80356530; ClinVar: pathogenic; called by mutect2, pindel
- TP53 | c.376-1G>C p.X126_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | hotspot (GDC flag); catalogued as CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; called by muse, mutect2
- ARHGAP15 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV54482215; called by muse, mutect2, varscan2
- ATP8A2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1349352729, COSV54945493; called by muse, mutect2
- CAMK2B | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs757353069; called by muse, varscan2
- CLSTN2 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV101515948; called by muse, mutect2, varscan2
- CORO6 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377722229; called by mutect2, varscan2
- CSMD3 | c.2757G>T p.L919F (on ENST00000297405 / NM_001363185.1; = p.L815F on NM_052900.3) | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52176901; called by mutect2, varscan2
- DNMT3B | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051749732, COSV99143013, COSV99144615; called by muse, mutect2, varscan2
- ESR1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779180038, COSV52782036; called by muse, mutect2, varscan2
- GLDC | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as rs1443669793; called by muse, mutect2, varscan2
- HRNR | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs144160623, COSV64260218; called by muse, mutect2, varscan2
- ITPR2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV67270089; called by muse, mutect2, varscan2
- MYH13 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs755306372, COSV52824168; called by muse, mutect2, varscan2
- MYO18B | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750092584; called by muse, mutect2, varscan2
- NCKAP1L | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs752125351, COSV53203384; called by muse, mutect2, varscan2
- NMNAT2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs201604722, COSV54267204; called by muse, mutect2, varscan2
- OBSCN | c.11059G>A p.V3687M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs748938488, COSV52751426; called by muse, mutect2, varscan2
- PCDHA3 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV63546162; called by muse, mutect2, varscan2
- PCDHA6 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs1206602805, COSV65342611; called by muse, mutect2, varscan2
- PHKA1 | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59811763; called by muse, varscan2
- PIK3R5 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1403513954, COSV52653221; called by muse, mutect2, varscan2
- PNMA8B | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66537789; called by muse, mutect2, varscan2
- POU4F2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs544750597, COSV55584502; called by muse, mutect2, varscan2
- RAD21 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 117/288 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.017); catalogued as rs750042081; called by muse, mutect2, varscan2
- RIMKLA | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV68909980; called by muse, mutect2, varscan2
- SLC38A3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs773457124; called by muse, mutect2, varscan2
- SLC52A3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606686, CM101476, COSV99447500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SREBF2 | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs556095599; called by muse, mutect2, varscan2
- TENM4 | c.8212G>A p.D2738N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs748290796; called by muse, mutect2, varscan2
- TMEM132C | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.66); catalogued as rs1464874228, COSV70671738; called by muse, mutect2
- TMEM179 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58794659; called by muse, mutect2
- TNNI1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs931098606, COSV60190191; called by muse, mutect2, varscan2
- TTN | c.66340G>A p.G22114S (on ENST00000591111; = p.G14690S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV100633035; called by muse, mutect2, varscan2
- ZIC1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.043); catalogued as COSV51553274; called by muse, mutect2
- ADAMTSL3 | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- AGBL1 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2
- APC | c.2868_2872del p.Y956* | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- BTK | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, varscan2
- CAPN6 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- CCNL1 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNNM1 | c.1946T>G p.F649C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CNOT4 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- CNTN1 | c.2350G>T p.V784F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- DGKB | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 28/584 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- ITGB3BP | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- KIF26A | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- KRTAP4-11 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- LCA5L | c.990G>C p.E330D | Missense Mutation (SNP) | VAF 85/716 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYH13 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- NCKAP5 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NPAS3 | c.341G>A p.W114* (on ENST00000356141 / NM_001164749.2; = p.W84* on NM_022123.3) | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- OR5M3 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSM | c.444C>A p.N148K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PAK1 | c.1083G>T p.M361I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PCIF1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PCM1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRAMEF17 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RWDD4 | c.432A>C p.K144N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SLC16A12 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK17A | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TECPR2 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.454); called by muse, varscan2
- UBOX5 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF773 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CALHM6 | c.48C>T p.S16= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1201594171; called by muse, mutect2, varscan2
- COL5A3 | c.2424C>T p.P808= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs142157715; called by muse, mutect2, varscan2
- CPNE7 | c.606C>A p.T202= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- CR1 | c.5304G>A p.V1768= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- CTNND2 | c.1392C>T p.V464= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs1465606234, COSV58887081; called by muse, mutect2
- DNAH5 | c.11769C>T p.A3923= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3501C>T p.A1167= (on ENST00000321322; = p.A1107= on NM_020693.4) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs749689834, COSV58388356, COSV58404199; called by muse, mutect2, varscan2
- FAT4 | c.1338G>A p.A446= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs1442421407, COSV67890861; called by muse, mutect2, varscan2
- GALNT10 | c.981G>A p.K327= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- HPSE | c.483G>A p.K161= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- LRP1B | c.11655T>A p.S3885= | Silent (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- MEX3B | c.873G>T p.S291= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1196103290, COSV61662920; called by muse, mutect2
- MYCBP2 | c.3342G>A p.A1114= (on ENST00000357337; = p.A1152= on NM_015057.5) | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs184772749, COSV62011039; called by muse, mutect2, varscan2
- RCC2 | c.1014C>T p.G338= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs147502663; called by muse, mutect2, varscan2
- RCN1 | c.87C>G p.A29= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- RIPOR2 | c.3099G>A p.L1033= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- TDRD15 | c.4869C>G p.T1623= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs759332257; called by muse, mutect2, varscan2
- UBE2O | c.546C>T p.C182= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- URGCP | c.2733G>A p.R911= (on ENST00000453200 / NM_001077663.3; = p.R902= on NM_017920.4) | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- VAT1L | c.450G>A p.P150= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs369885557; called by muse, varscan2
- WDR81 | c.4272C>T p.P1424= (on ENST00000409644 / NM_001163809.2; = p.P373= on NM_152348.4) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs138865714; called by muse, mutect2, varscan2
- YTHDC1 | c.406C>A p.R136= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV60011193; called by muse, mutect2, varscan2
- MIR888 | n.30C>T | RNA (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- STX11 | c.*132C>T | 3'UTR (SNP) | VAF 7/101 reads (7%) | catalogued as rs954452150; called by muse, mutect2
- TRIM61 | c.526-2757C>G | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
